Somatic mutation profile of tumor specimen 0DXOBA from CCDI case PBCRJT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.5 years (1,267 days).
Specimen 0DXOBA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16f6248f-947d-4d3f-bd79-77cddb058c6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXOAW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bff7c5c-e2bc-4141-a9a4-52e7cc86c94c

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 2, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPLX2 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 38/764 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1390253690; called by muse, mutect2
- IQSEC3 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 97/610 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58287413; called by muse, mutect2, varscan2
- PCDHB8 | c.697G>T p.V233F | Missense Mutation (SNP) | VAF 108/1961 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as rs782160543; called by muse, mutect2
- TRPV3 | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 76/447 reads (17%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.659); catalogued as COSV56791459; called by muse, mutect2, varscan2
- ZNF142 | c.4066C>T p.R1356W (on ENST00000411696 / NM_001379660.1; = p.R1156W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/441 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs756896397, COSV68743037; called by muse, mutect2, varscan2
- EFNA4 | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 78/538 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- FBN2 | c.7937A>C p.H2646P | Missense Mutation (SNP) | VAF 79/401 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1 | c.12162T>G p.Y4054* | Nonsense Mutation (SNP) | VAF 37/747 reads (5%) | called by muse, mutect2
- RECQL | c.1567G>A p.G523S | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- RNF213 | c.1614C>A p.F538L | Missense Mutation (SNP) | VAF 31/671 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2
- ZNF695 | c.1298A>C p.E433A | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF695 | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- KCNJ12 | c.66G>T p.L22= | Silent (SNP) | VAF 37/1530 reads (2%) | called by muse, mutect2
- SHFL | c.644-30C>A | Intron (SNP) | VAF 28/139 reads (20%) | called by muse, mutect2, varscan2
